HCMI case HCM-CSHL-0079-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/27e13777-6ed1-4411-a935-245ba6953cf5

Demographics
Sex at birth: male; Year of birth: 1941; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 75.9 years (27,727 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 4 or More; Peripancreatic lymph nodes tested: 42.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -19 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Nab-paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 324 days; Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day -9.

Molecular and laboratory tests
- CA19-9: 712.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Diabetes treatment type: Injected Insulin.
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 170 cm; BMI: 22.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Lifelong Non-Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0079-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0079-C25-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 9; Percent tumor nuclei: 13; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 71; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0079-C25-01A-01-S1-HE: Section location: Top; Percent tumor cells: 18; Percent tumor nuclei: 40; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 67; Percent lymphocyte infiltration: 26; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0079-C25-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0079-C25-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 53; Percent necrosis: 0; Percent stromal cells: 47; Percent lymphocyte infiltration: 48; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0079-C25-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 55; Percent necrosis: 0; Percent stromal cells: 45; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Samples HCM-CSHL-0079-C25-85A, HCM-CSHL-0079-C25-85B (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
